Somatic mutation profile of tumor specimen MP2PRT-PANSTA-TMP1-A (aliquot MP2PRT-PANSTA-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANSTA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (884 days).
Specimen MP2PRT-PANSTA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 294e1bce-6ae3-4f6e-ac2d-fdf277eb3139.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANSTA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANSTA-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38211ecc-cbbf-443f-ab15-472133362638

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6AP1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 61/678 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.636); catalogued as rs782690014; called by muse, mutect2
- OTOG | c.8072G>A p.R2691H | Missense Mutation (SNP) | VAF 248/538 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); catalogued as rs766229978, COSV61132507; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLXNB3 | c.3446G>A p.R1149H | Missense Mutation (SNP) | VAF 84/901 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs781889794; called by muse, mutect2
- PNMA8B | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 18/475 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs1280611702, COSV66536909; called by muse, mutect2
- SDK1 | c.5350G>A p.A1784T | Missense Mutation (SNP) | VAF 127/402 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761076885, COSV67355271; called by muse, mutect2, varscan2
- ZNF831 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 68/694 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs143620250, COSV100926147; called by muse, mutect2
- ZPLD1 | c.1064C>T p.S355L (on ENST00000466937 / NM_001329788.1; = p.S371L on NM_175056.2) | Missense Mutation (SNP) | VAF 20/327 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs369331610; called by muse, mutect2
- LCAT | c.1111_1112insGGGC p.T371Rfs*71 | Frame Shift Ins (INS) | VAF 192/486 reads (40%) | called by mutect2, pindel, varscan2
- PCDHAC1 | c.2290T>C p.S764P | Missense Mutation (SNP) | VAF 105/340 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SSC5D | c.1748G>A p.S583N | Missense Mutation (SNP) | VAF 154/377 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TTN | c.34265-5079G>A | Intron (SNP) | VAF 18/491 reads (4%) | catalogued as rs913650930, COSV59929921; called by muse, mutect2
